MMRF case MMRF_1755 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/df55ecae-7871-42da-bd85-195425f539e0

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.4 years (28,627 days); ISS stage: I; Days to last known disease status: 256 days; Days to last follow up: 256 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 205 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 206 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -53 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.443 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.1 mg/dL; Immunoglobulin G 22.8 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.89 mmol/L.
- Day 138 (ECOG 0): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.478 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.11 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 7.76 mmol/L.
- Day 256 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.292 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.773 mg/dL; Immunoglobulin G 3.37 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -53: Weight: 60 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample MMRF_1755_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -53 days.
- Sample MMRF_1755_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -53 days.
